Surgical pathology report (de-identified scan), TCGA case TCGA-KN-8428, project TCGA-KICH (Kidney Chromophobe), tissue source site Harvard, specimen TCGA-KN-8428-01A (Primary Tumor).

[page 1 of 4]
PATHOLOGIC DIAGNOSTICS:

SPECIMEN LABELED "LEFT KIDNEY":

RENAL CELL CARCINOMA (8.5 cm), Chromophobe type, Fuhrman Grade 3.

Lymphovascular invasion is not present.

Renal artery, renal vein and ureter margins negative for tumor.

No extension into perinephric tissue.

Soft tissue resection margin negative for tumor.

One (1) lymph node negative for tumor.

AJCC: T2N0Mx.

Two simple cysts (3.0 and 2.9 cm).

The non neoplastic kidney will be evaluated by Renal Pathology, and the findings will be reported in an addendum.

Immunoperoxidase: Tumor cells stain for colloidal iron.

CLINICAL DATA:

History: None given.

Operation: Left nephrectomy (laparoscopic).

Operative Findings: None given.

Clinical Diagnosis: Left renal mass.

ORGAN/TISSUE SUBMITTED:

1. Left kidney

GROSS DESCRIPTION:

The specimen is received fresh, in one part, labeled with the patient's name,

unit number, and "#1. Left kidney", and consists of an 858 g left radical

nephrectomy specimen including kidney with fat (28.8 x 12.1 x 6.7 cm),

ureter (11.5 x 3.5 cm in diameter; cauterized), vein (1.8 cm x 1.5 cm in

diameter; stapled), and renal artery (2.5 x 0.7 cm in diameter; stapled). No

adrenal gland is identified grossly. In the mid kidney is a tan/gray,

granular, well circumscribed solid/partially necrotic mass (8.5 x 7.5 x 6.5 cm)

that abuts the kidney capsule is 0.2 cm to the inked soft tissue resection margin.

[page 2 of 4]
3.0 cm to the artery, 0.9 cm to the vein, and 13.8 cm to the ureter resection margin. The tumor does not grossly extend beyond the kidney. The renal pelvis is distorted by abutting tumor. Additionally, there are two small foci within the renal pelvis suspicious for involvement by tumor. There are two thin walled cortical cysts (3.0 x 2.5 x 2.0 cm and 2.9 x 2.5 x 2.5 cm) in the inferior pole. Representative sections of tumor and normal kidney parenchyma are submitted for electron microscopy, cytogenetics, and the tissue banking. Representative sections are submitted for histology.

Micro A1: Ureter, artery and vein resection margins, 3 frags.
Micro A2: IL, 1 frag.
Micro A3: T2 from banking, 2 frags.
Micro A4 A6: Tumor with resection margin, 1 frag each.
Micro A7: Section of tumor with adjacent parenchyma, 1 frag.
Micro A8 A11: Tumor with renal pelvis, 1 frag each.
Micro A12: Tumor with surrounding pelvic fat, 1 frag.
Micro A13: Tumor with resection margin, 2 frags.
Micro A14: Tumor with normal parenchyma, 1 frag.
Micro A15: 3.0 cm cyst, 1 frag.
Micro A16: Normal kidney parenchyma, 1 frag.
Micro A17: 2.9 cm cyst, 1 frag.

By his/her signature below, the senior physician certifies that he/she personally conducted a microscopic examination ("gross only" exam if so stated) of the described specimen(s) and rendered or confirmed the diagnosis(es) related thereto.

RENAL PATHOLOGY EVALUATION OF NON-NEOPLASTIC RENAL PARENCHYMA:

LEFT KIDNEY, NEPHRECTOMY:

MILD TO MODERATE CHRONIC CHANGES OF THE KIDNEY PARENCHYMA, INCLUDING:

FOCAL GLOBAL GLOMERULOSCLEROSIS, MILD, PREDOMINANTLY SUBCAPSULAR, AND

MOST LIKELY SECONDARY TO VASCULAR DISEASE (9% OF GLOMERULI); TUBULAR ATROPHY AND INTERSTITIAL FIBROSIS, MILD TO MODERATE (20% OF PARENCHYMA); AND

[page 3 of 4]
ARTERIAL AND ARTERIOLAR SCLEROSIS AND HYALINOSIS, MODERATE
(SEE NOTE)

NOTE:

The chronic changes seen in the non-neoplastic parenchyma are rather non specific and do not point to a specific disease entity. The presence of glomeruli with an enlarged tuft suggests that the focal global and segmental glomerulosclerosis is most likely secondary to structural and functional adaptations. Glomerulosclerosis is frequently the final consequence of such adaptations that are brought about by hemodynamic changes and glomerular hypertrophy following loss of functioning nephrons. Such loss of nephrons is often the result of an independent primary glomerular, tubulo interstitial, or, most likely in this case, vascular disease. The proteinuria in patients with secondary focal and segmental glomerulosclerosis is most often slowly progressive, usually subnephrotic, and not accompanied by significant edema or hypoalbuminemia. Because the chronic changes seen here are most likely a result of functional adaptations to nephron loss from any glomerular, tubular, interstitial, vascular, or mass-replacing process, a similar degree of chronic damage would be expected in the contralateral kidney. This patient, therefore, may be at risk for persistent or progressive proteinuria and renal insufficiency.

Vascular sclerosis with parenchymal atrophy and sclerosis is often described under the misleading term of "benign nephrosclerosis" and ascribed and dismissed as secondary to hypertension, to a primary and advanced glomerulopathy, or to age related degenerative changes. Many other well-recognized forms of primary vascular injury can result in such changes on biopsy and are more likely to represent the cause of the vascular sclerosis and hypertension seen in this patient. Such vascular changes are often the result of a healed episode of HUS or TTP, pro-coagulant states (inherited pro-coagulant states or genetic thrombophilia, or acquired antiphospholipid antibody syndrome, etc.), autoimmune disorders (scleroderma, undifferentiated connective tissue disorders, overlap syndrome, etc.), toxic injury affecting components of the vascular wall (varicocytotoxin), antibody-mediated vascular injury (humoral rejection, etc.), substance abuse with drugs with vascular

[page 4 of 4]
toxicity (cocaine, amphetamines, pseudoephedrine, etc.), physical factors (irradiation, status post bone marrow transplantation), and, potentially, metabolic diseases with an important vascular component (gout, diabetes, hyperhomocysteinemia, etc.). The vascular involvement within the kidney in several of these conditions is well-established and documented, however, reports in the literature on the functional and structural effects on the kidney in many of the inherited and/or acquired thrombophilic states and some of the metabolic disorders is rather scant and often limited to anecdotal observations and case reports.

RECT 0399

The kidney parenchyma has been reviewed by Dr. Joel M. Henderson, Renal Pathologist.

REFERENCES:

Renske HG, Klein PS. Pathogenesis and significance of nonprimary focal and segmental glomerulosclerosis. Am J Kidney Dis 13:443-56, 1989.

MICROSCOPIC DESCRIPTION:

Sections of formalin-fixed, paraffin embedded tissue (block A15) were evaluated using H&E, PAS, Jones silver methenamine, and APOG (trichrome) stains.

The sample consists of cortex and medulla. There are 245 glomeruli present, of which 28 (9.0%) are globally sclerosed; most of the sclerosed glomeruli are present in a subcapsular distribution. The remaining glomeruli are slightly enlarged and show focal and mild expansion of the mesangial areas. On PAS and Jones' silver methenamine stains, there are no discernible craters or double contours of the glomerular capillary wall basement membranes. Several distal tubules contain PAS-positive hyaline casts, with lumina distention and with rare calcium deposits. The interstitium contains a mild mononuclear cell inflammatory infiltrate in areas of tubular atrophy. Approximately 20% of the cortical parenchyma shows tubular atrophy and interstitial fibrosis. Arteries exhibit a moderate degree of primarily subintimal sclerosis. Arterioles show focal sclerosis and hyalinosis of their walls.

RECT 0399

Source: NCI Genomic Data Commons file cf0107c1-a65d-4b48-8952-f432ccba680f (TCGA-KN-8428.206325F6-9479-4588-BC44-B0E1BCCDBEC3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).